Somatic mutation profile of tumor specimen C3L-01464-01 (aliquot CPT0085850009) from CPTAC case C3L-01464, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 78.7 years (28,740 days).
Specimen C3L-01464-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c29351e-866a-4433-8dbd-7df753192a45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01464-31 (Blood Derived Normal), aliquot CPT0086670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac3dc08-6c4e-479c-8c68-e40ebd6d51f4

The open-access MAF lists 130 somatic variants for this specimen: 86 protein-altering or splice-affecting, 28 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 28, Intron 9, Nonsense Mutation 9, Frame Shift Ins 5, Frame Shift Del 5, 3'UTR 4, Splice Site 3, RNA 2, In Frame Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH3 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762684007; called by muse, mutect2, varscan2
- CHD9 | c.5095C>G p.R1699G | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54608903; called by muse, mutect2, varscan2
- CHPF2 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367722805; called by muse, mutect2, varscan2
- CHRD | c.2219C>A p.P740Q | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52611557; called by muse, mutect2, varscan2
- FASTKD2 | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 41/561 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs367909050, COSV99379291; called by muse, mutect2
- FLNC | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | catalogued as COSV100367740; called by muse, mutect2, varscan2
- HMCN2 | c.12908C>T p.P4303L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758117010; called by muse, mutect2, varscan2
- KIF4B | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 54/397 reads (14%) | catalogued as COSV70528607; called by muse, mutect2, varscan2
- KRTAP13-3 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | catalogued as COSV61879624; called by muse, mutect2
- LDHA | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs148186234; called by muse, mutect2
- MOS | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61336392; called by muse, mutect2, varscan2
- MTOR | c.4451T>C p.L1484P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV63875792; called by muse, mutect2, varscan2
- PDE3A | c.446A>C p.Y149S | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs944406906, COSV62969222; called by muse, mutect2, varscan2
- PDLIM3 | c.571G>A p.V191I (on ENST00000284770 / NM_001257963.1; = p.V358I on NM_014476.6) | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1554037057; ClinVar: uncertain significance; called by muse, varscan2
- PLK3 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs749587381; called by muse, mutect2, varscan2
- PLXNB2 | c.5240C>T p.T1747I | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs752886171; called by muse, mutect2, varscan2
- PLXNB2 | c.1003del p.R335Gfs*56 | Frame Shift Del (DEL) | VAF 29/197 reads (15%) | catalogued as COSV100834388; called by mutect2, pindel, varscan2
- PPFIBP2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201767093, COSV55076609; called by muse, mutect2, varscan2
- SHANK2 | c.2017G>C p.V673L | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53617878; called by muse, mutect2
- SPATA2L | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354237080; called by muse, mutect2, varscan2
- STIM1 | c.1541+1G>A p.X514_splice | Splice Site (SNP) | VAF 28/166 reads (17%) | catalogued as rs1427379864; called by muse, mutect2, varscan2
- SYAP1 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV66468590; called by muse, mutect2, varscan2
- TCTN1 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs766834809; called by muse, mutect2, varscan2
- TTC30A | c.1232del p.K411Rfs*3 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | catalogued as rs1182821991; called by mutect2, varscan2
- ADAM23 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- AFM | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AGXT | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ARHGAP1 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARHGAP23 | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- ATAD2B | c.1498T>A p.S500T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- AUNIP | c.551dup p.L184Ffs*20 | Frame Shift Ins (INS) | VAF 28/184 reads (15%) | called by mutect2, pindel, varscan2
- BAP1 | c.506_516del p.H169Lfs*10 | Frame Shift Del (DEL) | VAF 65/390 reads (17%) | called by mutect2, pindel, varscan2
- BEND7 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- BICRAL | c.1060G>C p.V354L | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2
- BMP10 | c.334+1G>A p.X112_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- C17orf80 | c.615A>T p.K205N | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC88A | c.1518+2T>C p.X506_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | called by muse, varscan2
- CD300C | c.421_422insTA p.S141Ifs*24 | Frame Shift Ins (INS) | VAF 16/174 reads (9%) | called by mutect2, pindel
- CDIP1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- COL3A1 | c.2513C>A p.P838H | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- COQ10B | c.79_93del p.A27_V31del | In Frame Del (DEL) | VAF 16/132 reads (12%) | called by mutect2, pindel
- CRYBB2 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 25/283 reads (9%) | called by muse, mutect2
- CYFIP2 | c.3452T>A p.F1151Y (on ENST00000616178 / NM_001291722.2; = p.F1126Y on NM_014376.4) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DDX50 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF4A1 | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GLUL | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 61/432 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GMEB1 | c.277_282del p.I93_A94del | In Frame Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel, varscan2
- GPT | c.1314C>G p.F438L | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2
- KCNK5 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- LPP | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | called by mutect2, varscan2
- MARF1 | c.1778dup p.S594Efs*7 | Frame Shift Ins (INS) | VAF 27/209 reads (13%) | called by mutect2, pindel, varscan2
- MARS1 | c.2087T>A p.L696H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MATR3 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- MIA2 | c.347G>C p.S116T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.709); called by muse, varscan2
- MUC16 | c.23924T>C p.M7975T | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP155 | c.574G>T p.D192Y (on ENST00000231498 / NM_153485.3; = p.D133Y on NM_004298.4) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OGT | c.1093T>G p.S365A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDCD11 | c.4292G>T p.G1431V | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2
- PDS5A | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PEAK1 | c.3917A>C p.E1306A | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PGBD4 | c.834T>G p.Y278* | Nonsense Mutation (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.3152C>A p.T1051N | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABL6 | c.641T>C p.M214T | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RETREG1 | c.1240G>C p.G414R (on ENST00000306320 / NM_001034850.2; = p.G273R on NM_019000.4) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RPH3A | c.1723G>T p.V575L (on ENST00000389385 / NM_001143854.2; = p.V571L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2
- RTN4RL1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- SETD1B | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC41A2 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, varscan2
- SMG7 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPRED1 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTBN5 | c.6715G>T p.D2239Y | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- STKLD1 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SYNE2 | c.1499C>G p.S500* | Nonsense Mutation (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- SYTL2 | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- SZT2 | c.6233dup p.N2078Kfs*28 (on ENST00000634258 / NM_001365999.1; = p.N2021Kfs*28 on NM_015284.4) | Frame Shift Ins (INS) | VAF 45/216 reads (21%) | called by mutect2, pindel, varscan2
- TBR1 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- TIMD4 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TLN1 | c.3595T>C p.C1199R | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TP53RK | c.679_692del p.T227Gfs*10 | Frame Shift Del (DEL) | VAF 29/327 reads (9%) | called by mutect2, pindel
- TPR | c.4502A>C p.Q1501P | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- TRGV1 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- USP35 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ZCCHC3 | c.633del p.E211Dfs*4 | Frame Shift Del (DEL) | VAF 28/188 reads (15%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2863T>C p.Y955H | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF385A | c.960_961insT p.K321* (on ENST00000338010 / NM_001130967.3; = p.K301* on NM_015481.3) | Frame Shift Ins (INS) | VAF 23/135 reads (17%) | called by mutect2, pindel, varscan2
- ZNF852 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ABCA7 | c.6225G>A p.A2075= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs766708029; called by muse, mutect2
- ANKRD62 | c.36G>A p.R12= | Silent (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
- BICRAL | c.1062A>G p.V354= | Silent (SNP) | VAF 74/408 reads (18%) | called by muse, mutect2
- CELSR2 | c.4596C>T p.P1532= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs140880997; called by muse, mutect2, varscan2
- CHST5 | c.345C>T p.R115= | Silent (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- ELFN2 | c.309G>A p.S103= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as rs1278397255, COSV68743704; called by muse, mutect2, varscan2
- FAM102A | c.678C>T p.H226= (on ENST00000373095 / NM_001035254.3; = p.H84= on NM_203305.2) | Silent (SNP) | VAF 25/182 reads (14%) | called by muse, mutect2, varscan2
- GRID1 | c.6A>G p.E2= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2
- KCNQ2 | c.1140G>A p.G380= | Silent (SNP) | VAF 71/438 reads (16%) | catalogued as rs758286975; called by muse, varscan2
- KIAA1549L | c.4515C>T p.Y1505= (on ENST00000321505; = p.Y1802= on NM_012194.3) | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs551823874, COSV58587339; called by muse, mutect2, varscan2
- LHX6 | c.471C>T p.F157= (on ENST00000373755 / NM_001242334.2; = p.F186= on NM_014368.5) | Silent (SNP) | VAF 45/314 reads (14%) | catalogued as rs116345380, COSV61345626; called by muse, mutect2, varscan2
- METTL4 | c.1146G>T p.L382= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, varscan2
- MMRN1 | c.66C>T p.N22= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs147250620; called by muse, mutect2, varscan2
- MUC5B | c.345C>T p.N115= | Silent (SNP) | VAF 82/409 reads (20%) | catalogued as rs370501363; called by muse, mutect2, varscan2
- NAV2 | c.3564G>A p.R1188= (on ENST00000396087 / NM_001244963.2; = p.R1165= on NM_145117.5) | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- NPTX2 | c.1152C>T p.R384= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs748698114, COSV55716163; called by muse, mutect2, varscan2
- OTOF | c.354T>C p.Y118= | Silent (SNP) | VAF 53/349 reads (15%) | called by muse, mutect2
- PIK3R4 | c.2667T>A p.P889= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1184904856; called by muse, mutect2, varscan2
- POTEE | c.1635C>T p.H545= | Silent (SNP) | VAF 45/387 reads (12%) | catalogued as rs745763063, COSV58230928, COSV58232373; called by muse, mutect2, varscan2
- SLC45A4 | c.912C>T p.R304= (on ENST00000517878 / NM_001286646.2; = p.R253= on NM_001080431.2) | Silent (SNP) | VAF 33/222 reads (15%) | called by muse, mutect2, varscan2
- TBC1D2 | c.1419C>T p.S473= | Silent (SNP) | VAF 27/286 reads (9%) | catalogued as rs572368805; called by muse, mutect2, varscan2
- TRPC3 | c.759G>A p.L253= (on ENST00000379645 / NM_001366479.2; = p.L180= on NM_003305.2) | Silent (SNP) | VAF 14/315 reads (4%) | called by muse, mutect2
- TTC29 | c.702G>T p.L234= | Silent (SNP) | VAF 59/312 reads (19%) | called by muse, mutect2, varscan2
- UBN2 | c.285G>C p.P95= | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- UPP2 | c.402T>C p.H134= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as rs1439905089; called by muse, mutect2, varscan2
- VARS2 | c.3150G>A p.Q1050= | Silent (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2
- ZMYND8 | c.2754C>G p.A918= (on ENST00000311275 / NM_001363741.2; = p.A892= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/199 reads (11%) | catalogued as COSV53688805; called by muse, mutect2, varscan2
- ZNF503 | c.159C>A p.T53= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- AGAP1 | c.1051-30622C>G | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- AIF1 | c.196+59C>A | Intron (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- AL669831.1 | n.2989A>C | RNA (SNP) | VAF 62/453 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.*50T>G | 3'UTR (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- CYP27B1 | c.387-117dup | Intron (INS) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- DCAF17 | c.*1637G>A | 3'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs1214259258; called by muse, mutect2, varscan2
- HBE1 | c.-267+74685C>T | Intron (SNP) | VAF 59/346 reads (17%) | called by muse, mutect2, varscan2
- HSD17B2 | c.664+25T>C | Intron (SNP) | VAF 64/310 reads (21%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.2267C>G | RNA (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- MCFD2 | c.309+16del | Intron (DEL) | VAF 75/396 reads (19%) | called by mutect2, pindel, varscan2
- NUP50 | c.70-552C>A | Intron (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- PDE12 | c.1387+29T>C | Intron (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- PPIL2 | c.*126A>G | 3'UTR (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- PTPRS | c.-36C>A | 5'UTR (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- SRP19 | c.*525G>A | 3'UTR (SNP) | VAF 16/378 reads (4%) | catalogued as rs1193714124, COSV54842164; called by muse, mutect2
- TJP2 | c.342+32A>T | Intron (SNP) | VAF 58/331 reads (18%) | called by muse, mutect2, varscan2
